Somatic mutation profile of tumor specimen 0DPX3S from CCDI case PBCEBM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.4 years (5,611 days).
Specimen 0DPX3S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fc45310-5df1-42b6-94db-d78d268a52ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPX3A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5023b32-e4fb-4356-8c6e-e139c627e559

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH12 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 218/5083 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs147080212; called by muse, mutect2
- GUCY1A2 | c.2182C>T p.R728W | Missense Mutation (SNP) | VAF 90/3404 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV56496457; called by muse, mutect2
- ADTRP | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 62/2430 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRDL1 | c.279C>T p.C93= (on ENST00000372045; = p.C99= on NM_145234.4) | Silent (SNP) | VAF 127/1096 reads (12%) | catalogued as CM148184; called by muse, mutect2, varscan2
